Somatic mutation profile of tumor specimen 0DR1ZA from CCDI case PBCFTE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DR1ZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc8bb3e1-beca-4fef-be21-861e742d23d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR1YT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00c2aaea-eba9-4c12-9a14-4dfb8214bf68

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNTT | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 118/1035 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368773639, COSV100960570; called by muse, varscan2
- MTSS1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 224/929 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs763477158; called by muse, varscan2
- MUC5B | c.14389G>T p.A4797S | Missense Mutation (SNP) | VAF 404/1136 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV71594053; called by muse, varscan2
- NUP210 | c.3520G>T p.A1174S | Missense Mutation (SNP) | VAF 156/736 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54408495; called by muse, varscan2
- STOML2 | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 226/794 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); catalogued as COSV59716203; called by muse, varscan2
- IMPDH1 | c.1192G>A p.E398K (on ENST00000470772 / NM_001142573.2; = p.E484K on NM_000883.4) | Missense Mutation (SNP) | VAF 167/1522 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); called by muse, varscan2
- LTBP4 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 182/1122 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, varscan2
- MAML2 | c.2805A>C p.Q935H | Missense Mutation (SNP) | VAF 248/1476 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.233); called by muse, varscan2
- MFAP3L | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 68/560 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MYH1 | c.1537T>C p.F513L | Missense Mutation (SNP) | VAF 100/596 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, varscan2
- PLCH1 | c.1805C>A p.S602Y (on ENST00000340059 / NM_001130960.2; = p.S614Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 233/1170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CHD6 | c.6654C>T p.D2218= | Silent (SNP) | VAF 155/735 reads (21%) | called by muse, varscan2
- MLYCD | c.1182G>T p.L394= | Silent (SNP) | VAF 260/576 reads (45%) | called by muse, varscan2
- SRXN1 | c.162G>A p.P54= | Silent (SNP) | VAF 64/548 reads (12%) | called by muse, varscan2
- ADGRB2 | c.3353+28C>A | Intron (SNP) | VAF 84/510 reads (16%) | called by muse, varscan2
- MECOM | c.-189-1197C>T | Intron (SNP) | VAF 182/888 reads (20%) | catalogued as rs965026541; called by muse, varscan2
- SNTN | c.286-194C>G | Intron (SNP) | VAF 182/866 reads (21%) | called by muse, varscan2
